Somatic mutation profile of tumor specimen TCGA-RM-A68T-01A (aliquot TCGA-RM-A68T-01A-11D-A35D-08) from TCGA case TCGA-RM-A68T, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, malignant; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 46.7 years (17,065 days).
Specimen TCGA-RM-A68T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11d185b8-a09e-4738-b74f-726ccdd54c6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RM-A68T-10A (Blood Derived Normal), aliquot TCGA-RM-A68T-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2c9e135-45a7-4061-95fc-8d6c07402b0a

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAG2 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1350078621; called by muse, mutect2, varscan2
- ROBO1 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459828857, COSV71399261; called by muse, varscan2
- ZNF341 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266975199; called by muse, mutect2, varscan2
- ABCC9 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAHD1 | c.2287del p.L763Ffs*36 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- PLEKHA7 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- PPRC1 | c.3563G>A p.C1188Y | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ANKRD55 | c.1527G>T p.V509= | Silent (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
- FAM166A | c.468G>T p.G156= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- PSME4 | c.3615C>A p.I1205= | Silent (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
